Surgical pathology report (de-identified scan), TCGA case TCGA-06-0197, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0197-01A (Primary Tumor).

[page 1 of 2]
PATHOLOGICAL DIAGNOSIS:

PRELIMINARY DIAGNOSIS:

BRAIN, RIGHT FRONTAL: GLIOBLASTOMA MULTIFORME, (SEE DESCRIPTION AND COMMENT).

Operation/Specimen: Rt. frontal tumor bx. [REDACTED]

Clinical History and Pre-Op Dx: Rt. frontal brain tumor.

GROSS PATHOLOGY: Received unfixed and labeled with the patient's name, MRN and "right frontal brain tumor", are multiple soft tissue fragments aggregating to 1 x 1 x 0.5 cm. The largest tissue fragment is white-tan and somewhat firm. The smaller tissue fragments are red to tan with petechiae. The fragments are sectioned and representative tissues are submitted for touch imprints and smears.

INTRAOPERATIVE CONSULTATION, Cytologic smear diagnosis: "Brain, frontal, right: Malignant glioma, possibly glioblastoma multiforme. Rule-out glial sarcoma". [REDACTED]

After overnight formalin fixation, the tissue fragments are entirely submitted in three cassettes with the larger white, firm tissue fragments in cassettes 1&2 and the remainder of the tissue fragments in cassette 3.
[REDACTED]

MICROSCOPIC: Sections demonstrate a portion of brain parenchyma which is infiltrated by a neoplasm composed of pleomorphic cells with large irregular hyperchromatic nuclei and frequent mitoses. There are also areas of necrosis, vascular proliferation, sarcomatous-like areas, hemorrhage, and early organization of fibrin.

COMMENT: This is a malignant glioma with areas of necrosis, mitoses, and endothelial/vascular proliferation diagnostic of glioblastoma multiforme. Special stains to better characterize the sarcoma-like areas, and proliferation indices will be performed and issued as an addendum report.

[page 2 of 2]
TCGA-06-0197

ADDENDUM

FINAL REPORT: Masson-trichrome and GFAP stains show no areas of sarcoma or neoplastic fibroblastic proliferation. The MIB-1 stain shows a proliferation index of 15 to 20%. These features correlate with the H&E impression of glioblastoma multiforme.

SPECIAL STAINS: Trichrome and GFAP - negative for neoplastic fibroblastic proliferation. MIB-1 - mitotic proliferation index 15 to 20%.

Source: NCI Genomic Data Commons file bedd550a-fd8a-4047-a5f9-5d185ade8b34 (TCGA-06-0197.AE825F51-BAD6-490B-AAB5-DE19124CA57C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).